Somatic mutation profile of tumor specimen MP2PRT-PARXMC-TMP1-A (aliquot MP2PRT-PARXMC-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PARXMC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,526 days).
Specimen MP2PRT-PARXMC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f53f5205-7e0e-4ba5-b696-3dabaf6f5ff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXMC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXMC-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acdf1a72-539a-4220-9632-4e1cc403e76b

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Splice Site 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX20 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764811129, COSV63779731; called by muse, mutect2, varscan2
- DPP6 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 134/392 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100902352; called by muse, varscan2
- FBN3 | c.6616C>T p.R2206* | Nonsense Mutation (SNP) | VAF 80/186 reads (43%) | catalogued as rs150404330; called by muse, mutect2, varscan2
- LAMC3 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 127/373 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs779371261; called by muse, mutect2, varscan2
- MFSD10 | c.531+1G>T p.X177_splice | Splice Site (SNP) | VAF 63/223 reads (28%) | catalogued as COSV53273424; called by muse, mutect2, varscan2
- PA2G4 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 213/550 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57256221; called by muse, mutect2, varscan2
- PARP9 | c.878A>G p.E293G | Missense Mutation (SNP) | VAF 121/346 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1559867579, COSV64450987; called by muse, mutect2, varscan2
- RFX6 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100263130; called by muse, mutect2
- RIPOR3 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 108/352 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV50392033; called by muse, mutect2, varscan2
- SAE1 | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54296280; called by muse, mutect2, varscan2
- TRABD2B | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs758885728; called by muse, mutect2
- ACOT11 | c.758C>A p.A253E | Missense Mutation (SNP) | VAF 131/352 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DPYSL5 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 117/314 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GPATCH8 | c.2803T>C p.Y935H | Missense Mutation (SNP) | VAF 13/430 reads (3%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); called by muse, mutect2
- IGHV3-74 | chr14:106810431 del CTCACTGTGTCT | Missense Mutation (DEL) | VAF 73/174 reads (42%) | called by pindel, varscan2*
- IGLV8-61 | chr22:22099211 ins CG | In Frame Ins (INS) | VAF 78/349 reads (22%) | called by mutect2, pindel, varscan2
- NHSL1 | c.4775G>A p.S1592N | Missense Mutation (SNP) | VAF 181/487 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PPP3CA | c.120A>C p.K40N | Missense Mutation (SNP) | VAF 39/373 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- RBMXL3 | c.2870C>A p.P957H | Missense Mutation (SNP) | VAF 224/650 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TMEM150C | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2
- TRIM16L | c.485A>T p.D162V | Missense Mutation (SNP) | VAF 142/359 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBC | c.226G>T p.G76W | Missense Mutation (SNP) | VAF 46/568 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BHLHA9 | c.36G>A p.A12= | Silent (SNP) | VAF 153/436 reads (35%) | called by muse, mutect2, varscan2
- GATA4 | c.717C>T p.N239= | Silent (SNP) | VAF 170/277 reads (61%) | catalogued as rs747431380, COSV58735489; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT71 | c.711C>G p.L237= | Silent (SNP) | VAF 142/368 reads (39%) | called by muse, mutect2
- SPEG | c.2928C>T p.D976= | Silent (SNP) | VAF 176/502 reads (35%) | catalogued as rs896686548, COSV104395098; called by muse, mutect2, varscan2
